Somatic mutation profile of tumor specimen TCGA-EM-A4FU-01A (aliquot TCGA-EM-A4FU-01A-11D-A257-08) from TCGA case TCGA-EM-A4FU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 35.4 years (12,912 days).
Specimen TCGA-EM-A4FU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 801767a7-a950-4204-a819-a51475712bba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FU-10A (Blood Derived Normal), aliquot TCGA-EM-A4FU-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67696eaa-9305-4459-bf04-4b5d26aa22af

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 35/127 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV99267168; called by muse, mutect2, varscan2
- CEACAM4 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs112325334, COSV55731097, COSV99701080; called by muse, mutect2, varscan2
- NOL9 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100891542; called by muse, mutect2
- ZNF827 | c.2586G>C p.Q862H | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101061880; called by muse, mutect2
- ANKRD35 | c.1132C>T p.L378= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs782763154, COSV100841877; called by muse, mutect2, varscan2
